Surgical pathology report (de-identified scan), TCGA case TCGA-CD-5802, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site ILSBio, specimen TCGA-CD-5802-01A (Primary Tumor).

[page 1 of 6]
[REDACTED]

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the [REDACTED] **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

[REDACTED]

[REDACTED]

HISTORY OF PRESENT ILLNESS

Chief Complaints: *Difficult in swallowing; fever*

Symptoms: *Weight loss*

Clinical Findings:

Performance Scale (Karnofsky Score):

- ☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☒ 60-70 Symptomatic, in bed less than 50% of day
☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS

Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 6]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA						
Test	Result	Date		Test	Result	Date
				CEA	☐ Negative ☐ Positive: _____	
Hep B	☒ Negative ☐ Positive: _____	11		CA 15-3	☐ Negative ☐ Positive: _____	
Hep C	☒ Negative ☐ Positive: _____	11		CA 19-9	☐ Negative ☐ Positive: _____	
AFP	☐ Negative ☐ Positive: _____			PSA	☐ Negative ☐ Positive: _____	
Other:	☐ Negative ☐ Positive: _____			Other:	☐ Negative ☐ Positive: _____	
B/T Cell Markers:						

[page 3 of 6]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound		
X-Ray		
CT		
Endoscopy ✓	A tumor was found in the oesophagus.	
MRI		
Biopsy		

CLINICAL DIAGNOSIS	
Preoperative Clinical Diagnosis	
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis
Clinical Staging	
T ₃ N ₀ M ₀	Stage: II

Treatment Information

SURGICAL TREATMENT			
Procedure			Date of Procedure
1/3 of the oesophagus was removed.			
Primary Tumor			
Organ	Detailed Location	Size	
Stomach Tumor	Cardia	2.5 x 2 x 1 cm	
Extension of Tumor			
Lymph Nodes			
Description	Location of Lymph Nodes	# of Lymph Nodes	
Palpable, Non-Dissected Lymph Nodes			
Dissected Lymph Nodes			
Distant Metastasis			
Organ	Detailed Location	Size	
Surgical Staging			
T ₃ N ₀ M ₀		Stage: II	

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 6]
Pathology Form

Specimen Information

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
11 min		12 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Stomach Tumor	2.5 x 2 x 1 cm		6 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT ₃	N ₀	M ₀	Stage: II

Notes:

[page 5 of 6]
Microscopic Description

Histological Pattern											
Cell Distribution			+	-	Structural Pattern			+	-		
Diffuse			☒		Streaming						
Mosaic					Storiform						
Necrosis					Fibrosis						
Lymphocytic Infiltration			☒		Palisading						
Vascular Invasion					Cystic Degeneration						
Clusterized					Bleeding						
Alveolar Formation					Myxoid Change						
Indian File					Psammoma/Calcification						

Cellular Differentiation															
Squamous		+	-	Adenomatous		+	-	Sarcomatous		+	-	Lymphomatous		+	-
Squamoid Cell				Glandular cell		☒		Round Cell				Large Cell			
Spindle Cell				Cell Stratification				Fibroblast				Small Cell			
Keratin				Secretion				Osteoblast				RS Cell/RS Like			
Desmosome				Intracyt. Vacuole				Lipoblast				Inflam. Cell			
Pearl				Gland formation		☒		Myoblast				Plasma Cell			

Cellular Differentiation:	Well	Moderate ☒	Poor
----------------------------------	------	--	------

Nuclear Appearance				
Nuclear Atypia:	0	I	II	III
Aniso Nucleosis		☒		
Hyperchromatism			☒	
Nucleolar Prominent		☒		
Multinucleated Giant Cell			☒	
Mitotic Activity			☒	

Nuclear Grade:				
-----------------------	--	--	--	--

IHC Data			
Marker	Result	Value	Date
ER	☐ Negative ☐ Positive		
PR	☐ Negative ☐ Positive		
Her-2/neu	☐ Negative ☐ Positive		
B-Cell Marker	☐ Negative ☐ Positive		
T-Cell Marker	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		

Final Pathology Report

Histological Diagnosis: Adenocarcinoma of the stomach -
(moderate ly differentiated) Grade: II

Comments:

[page 6 of 6]
CONSOLIDATED DIAGNOSTIC PATHOLOGY FORM*

Microscopic Appearance:

1. Histological pattern:

CELL DISTRIBUTION			STRUCTURAL PATTERN		
	+	-		+	-
Diffuse		X	Streaming		
Mosaic	X		Storiform		
Necrosis		X	Fibrosis		
Lymphocytic Infiltration	X		Palisading		
Vascular Invasion		X	Cystic Degeneration		
Clusterized		X	Bleeding		
Alveolar Formation		X	Myxoid Change		
Indian File		X	Psamomma/Calcification		

2. Cellular features:

Squamous		Adenomatous		Sarcomatous		Lymphomatous	
	+	-		+	-		+
Squamoid Cell			Glandular cell	X		Large Cell	
Spindle Cell			Cell Stratification	X		Small Cell	
Keratin			Secretion	X		RS Cell/RS Like	
Desmosome			Intracyt. Vacuole	X		Inflam. Cell	
Pearl			Gland formation	X		Plasma Cell	
Otherwise Specified: D1 30% D2 40% D3 40% D4 30%							

2. Cellular Differentiation:

Well	Moderately	Poor
	X	

3. Nuclear Atypia:

Nuclear Appearance		0	I	II	III
Aniso Nucleosis			X		
Hyperchromatism			X		
Nucleolar Prominent				X	
Multinucleated Giant Cell				X	
Mitotic Activity				X	
Nuclear Grade				X	

Histological Diagnosis: Adenocarcinoma, G2

Source: NCI Genomic Data Commons file fcffe58b-33aa-4a6c-8857-24557d1d2ee4 (TCGA-CD-5802.46CB18FC-0B29-478B-8782-2C098259CCEE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).